Somatic mutation profile of tumor specimen HTMCP-03-06-02383-01A (aliquot HTMCP-03-06-02383-01A-01D-10409) from CGCI case HTMCP-03-06-02383, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2.
Specimen HTMCP-03-06-02383-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f080b586-116a-4116-98dd-b4c38ef2322d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02383-10A (Blood Derived Normal), aliquot HTMCP-03-06-02383-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/685374a7-8059-46df-8d71-07756647424e

The open-access MAF lists 79 somatic variants for this specimen: 63 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 9, Intron 4, Frame Shift Del 3, RNA 2, Nonsense Mutation 2, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID4A | c.3055G>A p.V1019I | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201016535; called by muse, mutect2, varscan2
- ATN1 | c.1285C>T p.Q429* | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | catalogued as COSV100755808; called by muse, mutect2, varscan2
- CBFA2T3 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV51931032; called by muse, mutect2, varscan2
- CSMD3 | c.4246G>A p.G1416S (on ENST00000297405 / NM_001363185.1; = p.G1312S on NM_052900.3) | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.531); catalogued as COSV52303596; called by muse, mutect2, varscan2
- CUL3 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.791); catalogued as COSV52370252; called by muse, mutect2, varscan2
- DNAH1 | c.3675C>A p.N1225K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs183711502; called by muse, mutect2, varscan2
- DST | c.8576A>G p.N2859S | Missense Mutation (SNP) | VAF 71/316 reads (22%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs745808070; called by muse, mutect2, varscan2
- HTT | c.6869G>T p.G2290V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as COSV61862433; called by muse, mutect2
- LSG1 | c.1213A>G p.T405A | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.456); catalogued as rs1375257877; called by muse, mutect2, varscan2
- MPDZ | c.3999C>G p.S1333R | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs772819227; called by muse, mutect2, varscan2
- MUC17 | c.8705C>T p.T2902I | Missense Mutation (SNP) | VAF 148/794 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.86); catalogued as rs1048395487; called by muse, mutect2, varscan2
- MUC2 | c.2458A>G p.S820G | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.17); catalogued as rs1449537060; called by muse, mutect2, varscan2
- NOS2 | c.1503G>T p.W501C | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1325435196; called by muse, mutect2, varscan2
- PCDHGA12 | c.2065C>T p.L689F | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as COSV52746559; called by muse, mutect2, varscan2
- PCLO | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs1485710322, COSV61643632; called by muse, varscan2
- PLCG2 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.998); catalogued as rs752906992, COSV63872484; called by muse, mutect2, varscan2
- ROBO2 | c.106C>A p.Q36K | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs769228923; called by muse, mutect2, varscan2
- SHROOM3 | c.4288C>T p.R1430* | Nonsense Mutation (SNP) | VAF 27/91 reads (30%) | catalogued as COSV99933404; called by muse, mutect2, varscan2
- SLK | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as rs1422106961; called by muse, mutect2, varscan2
- TEK | c.2304C>G p.I768M | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs370492416; called by muse, mutect2, varscan2
- TTC21A | c.825G>T p.K275N | Missense Mutation (SNP) | VAF 57/234 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs988114378, COSV57190194; called by muse, mutect2, varscan2
- TTN | c.67688G>T p.G22563V (on ENST00000591111; = p.G15139V on NM_003319.4) | Missense Mutation (SNP) | VAF 42/305 reads (14%) | PolyPhen probably damaging (1); catalogued as COSV100603595; called by muse, varscan2
- TTN | c.38777G>C p.R12926T (on ENST00000591111; = p.R5502T on NM_003319.4) | Missense Mutation (SNP) | VAF 37/207 reads (18%) | PolyPhen benign (0.049); catalogued as rs555652524; called by muse, mutect2, varscan2
- A2M | c.2540G>A p.C847Y | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ACIN1 | c.1828A>C p.K610Q | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- AKNAD1 | c.1014C>G p.I338M | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ALPK2 | c.3420G>C p.Q1140H | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- ATP7B | c.1944G>T p.K648N | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- CARMIL2 | c.587G>C p.G196A | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DNAH10 | c.5317G>C p.G1773R (on ENST00000409039; = p.G1712R on NM_207437.3) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- DOCK8 | c.5617G>C p.D1873H | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- EP300 | c.3295C>G p.L1099V | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EPB41L3 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- EPC2 | c.1986C>A p.H662Q | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ERCC6L | c.2505C>G p.S835R | Missense Mutation (SNP) | VAF 61/254 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FBN3 | c.1017C>T p.S339= | Splice Region (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- FLNB | c.4617C>A p.D1539E | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FMO5 | c.288del p.E98Nfs*5 | Frame Shift Del (DEL) | VAF 26/210 reads (12%) | called by mutect2, pindel, varscan2
- GABBR2 | c.1527G>C p.Q509H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HYDIN | c.7209A>C p.K2403N | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ITGB1BP2 | c.860G>C p.R287P | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KIF1B | c.3929A>G p.D1310G (on ENST00000377086 / NM_001365952.1; = p.D1264G on NM_015074.3) | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- KLHL14 | c.1495G>C p.A499P | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LCT | c.491A>T p.D164V | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- MDGA2 | c.803del p.K268Rfs*3 | Frame Shift Del (DEL) | VAF 40/146 reads (27%) | called by mutect2, pindel, varscan2
- MYBPC2 | c.1008del p.F336Lfs*12 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- MYO3A | c.4174A>T p.N1392Y | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- NRXN3 | c.1103C>A p.T368N | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OAS3 | c.2855G>C p.W952S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OGA | c.1435A>T p.N479Y | Missense Mutation (SNP) | VAF 110/428 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- OLFM3 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPS6KC1 | c.1202T>A p.F401Y | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RTTN | c.3860A>T p.K1287M | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- SCN9A | c.5462T>C p.V1821A (on ENST00000303354; = p.V1810A on NM_002977.3) | Missense Mutation (SNP) | VAF 73/371 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- TRHDE | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); called by muse, mutect2
- TTN | c.26507C>A p.T8836N (on ENST00000591111; = p.T7909N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/243 reads (43%) | PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TTN | c.11452A>C p.N3818H (on ENST00000591111; = p.N3772H on NM_003319.4) | Missense Mutation (SNP) | VAF 39/237 reads (16%) | called by muse, mutect2, varscan2
- UNC79 | c.4721G>C p.R1574P (on ENST00000393151 / NM_001346218.2; = p.R1397P on NM_020818.5) | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- VWA5B1 | c.2330C>G p.S777C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- WDFY4 | c.2586T>G p.S862R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDFY4 | c.2587C>T p.H863Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF607 | c.2074C>G p.Q692E | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- ZNF99 | c.2237C>T p.S746L | Missense Mutation (SNP) | VAF 59/262 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BCORL1 | c.1704G>T p.L568= | Silent (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- DDR2 | c.903G>A p.E301= | Silent (SNP) | VAF 50/284 reads (18%) | catalogued as rs748822715; called by muse, mutect2, varscan2
- DNHD1 | c.9330C>T p.V3110= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs530996261; called by muse, mutect2, varscan2
- ENTR1 | c.381G>A p.P127= (on ENST00000357365 / NM_001039707.2; = p.P104= on NM_006643.4) | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs537523204; called by muse, mutect2, varscan2
- FMN2 | c.1260G>A p.K420= | Silent (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- NALCN | c.2595T>A p.P865= | Silent (SNP) | VAF 17/190 reads (9%) | called by muse, mutect2
- OBSCN | c.11391C>T p.V3797= | Silent (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- PAPPA2 | c.4602C>A p.A1534= | Silent (SNP) | VAF 30/128 reads (23%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.1563C>A p.I521= | Silent (SNP) | VAF 25/48 reads (52%) | called by muse, mutect2, varscan2
- AC093787.2 | n.49G>C | RNA (SNP) | VAF 18/44 reads (41%) | called by muse, varscan2
- ANO2 | c.1343-518C>A | Intron (SNP) | VAF 63/261 reads (24%) | called by muse, mutect2, varscan2
- DCHS2 | n.4819C>A | RNA (SNP) | VAF 31/201 reads (15%) | called by muse, mutect2, varscan2
- DST | c.1146-229C>G | Intron (SNP) | VAF 64/164 reads (39%) | called by muse, mutect2, varscan2
- MIR663B | chr2:132257963 G>A | 5'Flank (SNP) | VAF 9/24 reads (38%) | catalogued as rs1409816545; called by muse, mutect2, varscan2
- ZNF185 | c.1209-3506C>A | Intron (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- ZNF185 | c.1209-3505C>A | Intron (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
